Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A2JF, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A2JF-06A (Metastatic).

[page 1 of 2]
Prior Malignancy History	Noted on CQCF	X

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

Patient ID - - Sample ID

ICD-0-3

Melanoma, NOS 8720/3

Site: Subcutaneous tissue, arm C49.1

hw 7/24/11

(A) LEFT UPPER ARM NODULE, SKIN ELLIPSE:

MELANOMA INVOLVING DERMIS AND SUBCUTANEOUS TISSUE, TISSUE EDGES APPEAR FREE.
TUMOR SIZE: 20 MM X 20 MM (AS PER GROSS DESCRIPTION).
TUMOR BORDER: INFILTRATIVE.

(B) LEFT FOREARM NODULE, SKIN ELLIPSE:

MELANOMA INVOLVING DERMIS AND SUBCUTANEOUS TISSUE, WITHIN 0.6 MM OF PERIPHERAL TISSUE EDGE.
TUMOR SIZE: 11 MM X 10 MM (AS PER GROSS DESCRIPTION).
TUMOR BORDER: INFILTRATIVE.

An immunohistochemical study will be performed to try to detect expression of melanocytic markers and an addendum report will follow.

GROSS DESCRIPTION

(A) LEFT UPPER ARM NODULE – An ellipse of tan-white skin (5.5 x 2.0 cm, excised to a depth of 2.2 cm). The specimen is not oriented. The epidermal surface is unremarkable. Sectioning reveals a well-circumscribed nodule (2.0 x 2.0 x 1.8 cm) and it is 0.8 cm from deep margin and 0.5 cm from peripheral margin.

INK CODE: Yellow – one margin, blue – opposite margin, black – deep margin.

SECTION CODE: A1, tips of the ellipse, ink side up; A2-A4, nodule.

(B) LEFT FOREARM NODULE – An ellipse of tan wrinkled skin (2.5 x 1.0 cm, excised to a depth of 1.5 cm). The specimen is not oriented. The epidermal surface is unremarkable. Sectioning reveals a well-circumscribed tan firm nodule (1.1 x 1.0 x 0.8 cm) and it is 0.3 cm from deep margin and 0.4 cm from peripheral margin.

INK CODE: Yellow – peripheral margin, blue – the other peripheral margin, black – deep margin.

SECTION CODE: B1, tips of the ellipse, ink side up; B2, nodule, old; B3, remainder of the specimen.

CLINICAL HISTORY

None given.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

. These tests have not been

Start of ADDENDUM

[page 2 of 2]
ADDENDUM

This modified report is being issued to report special studies/IHC/Molecular studies.

Addendum completed by

COMMENT

Panmelanoma cocktail (HMB45, anti-MART1, anti-tyrosinase) labels scattered tumor cells thus supporting the diagnosis of metastatic melanoma.

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file b8d4bbdf-08c5-43d7-ab66-3c7d01493665 (TCGA-D3-A2JF.80C97CF8-9325-48B5-A944-F6DF61ADD6A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).